CCDI case PBCDBS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/68104d91-4fc9-42c5-8a6e-f8fb12d1678d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.8 years (4,297 days).

Biospecimens (3 samples)
- Sample 0DPAO7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPAOI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DPAOP: Tissue type: Tumor; Specimen type: Solid Tissue.
